Somatic mutation profile of cancer-model specimen HCM-BROD-0118-C16-85A (3D Organoid, passage 5; aliquot HCM-BROD-0118-C16-85A-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0118-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: GX; Age at diagnosis: 46.0 years (16,790 days).
Specimen HCM-BROD-0118-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98b3569b-7413-48a0-9a67-1fc742ca5336.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0118-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0118-C16-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3896559-b83d-4f6b-bb1c-38b521a17c86

The open-access MAF lists 180 somatic variants for this specimen: 131 protein-altering or splice-affecting, 41 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 41, Nonsense Mutation 6, Frame Shift Del 4, In Frame Ins 3, Intron 3, Splice Region 3, 5'UTR 3, Frame Shift Ins 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 125/125 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 312/371 reads (84%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1190331077; called by muse, mutect2, varscan2
- AC105001.2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs377715499; called by muse, mutect2, varscan2
- AHNAK2 | c.4682T>C p.L1561P | Missense Mutation (SNP) | VAF 185/495 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV60929921; called by muse, mutect2, varscan2
- ATP2B3 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 544/544 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782151825, COSV54845659; called by muse, mutect2, varscan2
- C20orf141 | c.373T>G p.S125A | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs547675503; called by muse, mutect2
- CD248 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 281/577 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.365); catalogued as rs991947564; called by muse, mutect2, varscan2
- CEP295NL | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs367913374; called by muse, mutect2, varscan2
- CHD7 | c.6589G>A p.D2197N | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs772379262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL2A1 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 132/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475320, COSV61535514; called by muse, mutect2, varscan2
- CPEB1 | c.797G>A p.R266H (on ENST00000617958; = p.R206H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/323 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1361276650; called by muse, mutect2, varscan2
- CTBP2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 167/494 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as rs781768901; called by muse, mutect2, varscan2
- DCC | c.1153T>G p.L385V | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59087954; called by muse, mutect2, varscan2
- DERA | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 129/130 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs774189773; called by muse, mutect2, varscan2
- DHX38 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 177/364 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs369133069; called by muse, mutect2, varscan2
- DLL1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 325/719 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs200801825; called by muse, mutect2, varscan2
- EFCAB6 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 116/232 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs768065922; called by muse, mutect2, varscan2
- ERICH3 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 125/253 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as rs1393569433, COSV58599461; called by muse, mutect2, varscan2
- EXT2 | c.190C>T p.R64C (on ENST00000343631; = p.R97C on NM_000401.3) | Missense Mutation (SNP) | VAF 155/329 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs745846072; called by muse, mutect2, varscan2
- FHL5 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV58736831; called by muse, mutect2, varscan2
- GAN | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 141/297 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1330501647; called by muse, mutect2, varscan2
- GPAT3 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 93/315 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as rs760068026; called by muse, mutect2, varscan2
- HDLBP | c.2671C>A p.P891T | Missense Mutation (SNP) | VAF 175/353 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100190921; called by muse, mutect2, varscan2
- IKZF1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 153/335 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497805, COSV58793633; called by muse, mutect2, varscan2
- ITGAD | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs182955563, COSV54932632, COSV99791380; called by muse, mutect2, varscan2
- NEK4 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 97/250 reads (39%) | catalogued as rs771482582, COSV51780821; called by muse, mutect2, varscan2
- NPHP3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 320/657 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.881); catalogued as rs1465502034, COSV100446713; called by muse, mutect2, varscan2
- NSDHL | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 170/381 reads (45%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs782205394, COSV64743670; called by muse, mutect2, varscan2
- PRICKLE1 | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 172/407 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV58210761; called by muse, mutect2, varscan2
- PRICKLE2 | c.1921G>C p.E641Q (on ENST00000295902; = p.E585Q on NM_198859.4) | Missense Mutation (SNP) | VAF 166/337 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99896845; called by muse, mutect2, varscan2
- PTPRD | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV61981297; called by muse, mutect2, varscan2
- RAD54L2 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 157/322 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1463503723; called by muse, mutect2, varscan2
- RNF34 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555282169; called by muse, varscan2
- SHANK3 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 188/399 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1448376623, COSV99436944; called by muse, mutect2, varscan2
- SIDT1 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.974); catalogued as rs779212591, COSV53507931; called by muse, mutect2, varscan2
- SKIDA1 | c.1166C>G p.S389W | Missense Mutation (SNP) | VAF 246/881 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1384007416; called by muse, varscan2
- SKOR1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 340/960 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1281085160; called by muse, varscan2
- SLIT2 | c.2535C>A p.F845L | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99885564; called by muse, mutect2, varscan2
- SMPDL3B | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 196/334 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144852835; called by muse, mutect2, varscan2
- SPART | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 140/414 reads (34%) | catalogued as rs776372801; called by muse, mutect2, varscan2
- THSD7B | c.3236G>A p.R1079K (on ENST00000272643; = p.R1077K on NM_001316349.2) | Missense Mutation (SNP) | VAF 119/223 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs1423425617; called by muse, mutect2, varscan2
- TTC30A | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 212/434 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1448523643, COSV53697385, COSV99610615, COSV99610790; called by muse, mutect2, varscan2
- VANGL2 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 229/430 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781038004, COSV63604080; called by muse, mutect2, varscan2
- WDR38 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 217/424 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1424090984; called by muse, mutect2, varscan2
- WDR81 | c.4943C>T p.S1648L (on ENST00000409644 / NM_001163809.2; = p.S597L on NM_152348.4) | Missense Mutation (SNP) | VAF 362/362 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs781192587, COSV58488341; called by muse, mutect2
- ZBP1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 94/399 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs765287829, COSV100472960; called by muse, varscan2
- ZNF596 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs148785316; called by muse, mutect2, varscan2
- ADAM7 | c.171A>C p.E57D | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ADIPOR1 | c.829A>G p.S277G | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); called by muse, mutect2
- AHDC1 | c.1400A>T p.K467M | Missense Mutation (SNP) | VAF 19/576 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- ANAPC4 | c.881A>C p.K294T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AUP1 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- BCAP31 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 181/405 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CDK5 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDYL2 | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 124/294 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CFAP94 | c.997G>A p.E333K (on ENST00000320267 / NM_001352064.2; = p.E339K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CFH | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHST13 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 278/534 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2
- CNTN3 | c.101A>C p.N34T | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- COL4A1 | c.1808dup p.G604Wfs*13 | Frame Shift Ins (INS) | VAF 192/949 reads (20%) | called by mutect2, pindel, varscan2
- CPNE9 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CTNND1 | c.1180T>C p.C394R | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- DSCAML1 | c.1498A>G p.T500A (on ENST00000321322; = p.T440A on NM_020693.4) | Missense Mutation (SNP) | VAF 23/714 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); called by muse, mutect2
- DZIP1 | c.1625_1626del p.R542Nfs*17 (on ENST00000347108; = p.R523Nfs*17 on NM_014934.5) | Frame Shift Del (DEL) | VAF 151/780 reads (19%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.929A>G p.E310G | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- EQTN | c.533_540del p.L178Qfs*22 | Frame Shift Del (DEL) | VAF 161/330 reads (49%) | called by pindel, varscan2
- EXOC6B | c.2247T>G p.Y749* | Nonsense Mutation (SNP) | VAF 167/324 reads (52%) | called by muse, mutect2, varscan2
- FAM13B | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.391); called by muse, varscan2
- FECH | c.192G>A p.K64= | Splice Region (SNP) | VAF 137/414 reads (33%) | called by muse, mutect2, varscan2
- FGF1 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 17/421 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- FNTA | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 108/218 reads (50%) | called by muse, mutect2, varscan2
- FOSB | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- FSIP2 | c.19766G>A p.R6589K | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPC6 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 147/619 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR108 | c.1438T>G p.L480V (on ENST00000264080 / NM_001080452.1; = p.L238V on NM_020171.2) | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2
- HR | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 126/327 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- JADE2 | c.1333A>T p.T445S | Missense Mutation (SNP) | VAF 191/422 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- JAK1 | c.3243T>G p.D1081E | Missense Mutation (SNP) | VAF 111/245 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.15179T>A p.L5060H | Missense Mutation (SNP) | VAF 29/566 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- KRT27 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 164/4782 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.383); called by muse, mutect2
- KRTAP13-1 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 122/340 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- LARGE1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 122/240 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.319-1_319insCAA p.L106_I107insQ | In Frame Ins (INS) | VAF 173/368 reads (47%) | called by muse*, mutect2, varscan2*
- MAGEC2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 208/437 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- MAGI2 | c.4256del p.P1419Rfs*55 | Frame Shift Del (DEL) | VAF 110/234 reads (47%) | called by mutect2, pindel, varscan2
- MAGI2 | c.2334T>G p.D778E | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MANF | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 115/241 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K7 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 164/165 reads (99%) | called by muse, mutect2, varscan2
- MGA | c.1919A>T p.K640M | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MTHFD1L | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- MYO15A | c.3908T>C p.L1303P | Missense Mutation (SNP) | VAF 20/708 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- MYT1 | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 200/875 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- NAGPA | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 287/529 reads (54%) | PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NELFB | c.1823A>C p.Q608P | Missense Mutation (SNP) | VAF 282/550 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NETO1 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLGN1 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 121/416 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NUDT14 | c.426C>T p.Y142= | Splice Region (SNP) | VAF 127/274 reads (46%) | called by muse, mutect2, varscan2
- NUP85 | c.889_895dup p.E299Afs*7 | Frame Shift Ins (INS) | VAF 77/210 reads (37%) | called by mutect2, varscan2
- OR10S1 | c.577T>C p.C193R | Missense Mutation (SNP) | VAF 144/334 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR51B4 | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- PCSK9 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 256/487 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C2G | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 98/348 reads (28%) | called by muse, mutect2, varscan2
- PIP5K1B | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 139/259 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PPIL2 | c.1406_1422del p.G469Dfs*72 (on ENST00000335025 / NM_148175.3; = p.G469Dfs*105 on NM_014337.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 154/439 reads (35%) | called by mutect2, pindel, varscan2
- PTBP1 | c.1316A>C p.K439T (on ENST00000349038 / NM_031991.4; = p.K465T on NM_002819.5) | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PTPRM | c.1981T>A p.F661I | Missense Mutation (SNP) | VAF 17/430 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2
- RLF | c.2918A>G p.K973R | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- RNPC3 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SERPINB9 | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 109/215 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SERPINE2 | c.295_297dup p.I99dup | In Frame Ins (INS) | VAF 105/260 reads (40%) | called by mutect2, pindel, varscan2
- SERPINI1 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 122/417 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SLIT2 | c.2536A>T p.N846Y | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SMARCE1 | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 153/3890 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2
- SNTB1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.645A>T p.R215S | Missense Mutation (SNP) | VAF 26/496 reads (5%) | PolyPhen benign (0.03); called by muse, mutect2
- SUDS3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 180/351 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SYNE1 | c.15736G>A p.E5246K (on ENST00000367255 / NM_182961.4; = p.E5175K on NM_033071.3) | Missense Mutation (SNP) | VAF 190/386 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TANC1 | c.407_408insGTTCCA p.Q136_E137insFQ | In Frame Ins (INS) | VAF 97/229 reads (42%) | called by mutect2, pindel, varscan2
- TBCCD1 | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- TLN2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 119/374 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TNPO2 | c.435A>T p.G145= | Splice Region (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- TRAF6 | c.652T>A p.C218S | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBA7 | c.2426A>G p.E809G | Missense Mutation (SNP) | VAF 13/281 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2
- VPS13D | c.7411A>C p.T2471P | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WLS | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); called by muse, mutect2
- XKR5 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2
- ZNF257 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF469 | c.5232G>C p.Q1744H (on ENST00000437464; = p.Q1772H on NM_001367624.2) | Missense Mutation (SNP) | VAF 21/587 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2
- ZNF599 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 207/414 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF880 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 136/334 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- BPTF | c.108C>T p.I36= | Silent (SNP) | VAF 316/615 reads (51%) | called by muse, mutect2, varscan2
- BST2 | c.102C>T p.I34= | Silent (SNP) | VAF 192/236 reads (81%) | catalogued as rs1408717756, COSV53089403; called by muse, mutect2, varscan2
- CALN1 | c.645G>A p.R215= (on ENST00000329008 / NM_001017440.3; = p.R257= on NM_031468.4) | Silent (SNP) | VAF 116/242 reads (48%) | catalogued as COSV61123899; called by muse, mutect2, varscan2
- COL16A1 | c.3219C>G p.L1073= | Silent (SNP) | VAF 186/395 reads (47%) | called by muse, mutect2, varscan2
- COL5A2 | c.4275C>T p.L1425= | Silent (SNP) | VAF 112/264 reads (42%) | called by muse, mutect2, varscan2
- CUBN | c.195C>T p.T65= | Silent (SNP) | VAF 110/446 reads (25%) | catalogued as rs373954380; called by muse, mutect2, varscan2
- DNAH17 | c.4374C>T p.N1458= | Silent (SNP) | VAF 166/346 reads (48%) | called by muse, mutect2, varscan2
- DNM1 | c.69C>T p.I23= | Silent (SNP) | VAF 295/578 reads (51%) | catalogued as rs1260683636; called by muse, mutect2, varscan2
- FAM114A2 | c.1143C>T p.S381= | Silent (SNP) | VAF 126/287 reads (44%) | called by muse, mutect2, varscan2
- FAM120C | c.135G>A p.P45= | Silent (SNP) | VAF 316/318 reads (99%) | called by muse, varscan2
- FAT4 | c.5796C>T p.F1932= | Silent (SNP) | VAF 105/193 reads (54%) | catalogued as COSV100628248, COSV100629757; called by muse, mutect2, varscan2
- FRMPD2 | c.3420G>A p.T1140= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1417835810; called by mutect2, varscan2
- GPR157 | c.318C>T p.L106= | Silent (SNP) | VAF 28/608 reads (5%) | catalogued as COSV66233836; called by muse, mutect2
- HMCN2 | c.13656C>A p.G4552= | Silent (SNP) | VAF 198/422 reads (47%) | catalogued as rs148355972; called by mutect2, varscan2
- IKZF3 | c.1062T>C p.G354= | Silent (SNP) | VAF 170/5232 reads (3%) | called by muse, mutect2
- ILVBL | c.1767C>A p.L589= | Silent (SNP) | VAF 206/248 reads (83%) | catalogued as rs1429240647, COSV54621281, COSV99655084; called by muse, mutect2, varscan2
- IRAK1BP1 | c.72G>A p.E24= | Silent (SNP) | VAF 170/314 reads (54%) | catalogued as rs1467655410, COSV64047854; called by muse, mutect2, varscan2
- KLHL29 | c.2037C>T p.L679= | Silent (SNP) | VAF 160/371 reads (43%) | catalogued as rs866239614, COSV56026124; called by muse, mutect2, varscan2
- LRBA | c.7200A>G p.S2400= | Silent (SNP) | VAF 121/213 reads (57%) | catalogued as rs1456691130, COSV63953568; called by muse, mutect2, varscan2
- NEXMIF | c.3441C>T p.V1147= | Silent (SNP) | VAF 204/204 reads (100%) | called by muse, mutect2, varscan2
- NLRP5 | c.1263C>T p.V421= | Silent (SNP) | VAF 128/342 reads (37%) | catalogued as rs763332031, COSV66763079, COSV66763950; called by muse, mutect2, varscan2
- NUP188 | c.78G>C p.L26= | Silent (SNP) | VAF 119/249 reads (48%) | catalogued as rs112594279, COSV65361459, COSV65362125; called by muse, mutect2, varscan2
- PCDHB9 | c.2124C>T p.F708= | Silent (SNP) | VAF 230/605 reads (38%) | catalogued as rs1179429492; called by muse, mutect2, varscan2
- PCLO | c.2544C>T p.P848= | Silent (SNP) | VAF 163/320 reads (51%) | catalogued as rs375555006; called by muse, mutect2, varscan2
- PKHD1 | c.10614C>T p.I3538= | Silent (SNP) | VAF 97/211 reads (46%) | catalogued as rs1348569812; called by muse, mutect2, varscan2
- PNMT | c.708G>A p.E236= | Silent (SNP) | VAF 190/7022 reads (3%) | catalogued as rs375815275; called by muse, mutect2
- RIMS1 | c.4077C>T p.L1359= | Silent (SNP) | VAF 125/286 reads (44%) | called by muse, mutect2, varscan2
- SLC20A2 | c.699C>T p.F233= | Silent (SNP) | VAF 102/198 reads (52%) | catalogued as rs149457553; called by muse, mutect2, varscan2
- SLC22A12 | c.486G>A p.A162= | Silent (SNP) | VAF 153/354 reads (43%) | catalogued as rs376212424; called by muse, mutect2
- SLC51A | c.477C>T p.P159= | Silent (SNP) | VAF 161/588 reads (27%) | called by mutect2, varscan2
- SLCO5A1 | c.258G>A p.P86= | Silent (SNP) | VAF 186/414 reads (45%) | catalogued as rs777138818, COSV52657734; called by muse, varscan2
- SOBP | c.1830C>T p.P610= | Silent (SNP) | VAF 227/495 reads (46%) | called by muse, mutect2, varscan2
- SPIDR | c.2616G>A p.V872= | Silent (SNP) | VAF 95/220 reads (43%) | called by muse, varscan2
- SYT17 | c.396C>T p.L132= | Silent (SNP) | VAF 122/322 reads (38%) | catalogued as COSV62545695; called by muse, mutect2, varscan2
- TENM4 | c.1158A>C p.T386= | Silent (SNP) | VAF 128/310 reads (41%) | called by muse, mutect2, varscan2
- TIAM1 | c.387T>C p.T129= | Silent (SNP) | VAF 195/401 reads (49%) | catalogued as COSV99734390; called by muse, mutect2, varscan2
- TMEM161A | c.183A>G p.K61= | Silent (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- USF3 | c.3474G>A p.R1158= | Silent (SNP) | VAF 165/347 reads (48%) | catalogued as COSV57077529; called by muse, mutect2, varscan2
- VAV1 | c.834C>T p.L278= | Silent (SNP) | VAF 161/161 reads (100%) | catalogued as rs748216879, COSV58380025; called by muse, mutect2, varscan2
- ZFHX4 | c.8451C>T p.D2817= | Silent (SNP) | VAF 175/398 reads (44%) | catalogued as rs746820985, COSV50496015; called by muse, mutect2, varscan2
- ZSCAN1 | c.414C>T p.F138= | Silent (SNP) | VAF 312/313 reads (100%) | catalogued as rs147151087; called by muse, mutect2, varscan2
- ALKBH6 | c.-11A>G | 5'UTR (SNP) | VAF 13/278 reads (5%) | called by muse, mutect2
- ATP5PF | c.-98G>T | 5'UTR (SNP) | VAF 218/423 reads (52%) | called by muse, mutect2, varscan2
- DST | c.4296+3907A>C | Intron (SNP) | VAF 15/426 reads (4%) | called by muse, mutect2
- GLB1L3 | c.877-1951C>T | Intron (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- KCNQ1 | c.1393+33785T>G | Intron (SNP) | VAF 114/114 reads (100%) | called by muse, mutect2
- LYSMD4 | chr15:99733378 GGCG>CC | 5'Flank (DEL) | VAF 148/772 reads (19%) | called by pindel, varscan2*
- NPEPL1 | chr20:58691207 T>G | 5'Flank (SNP) | VAF 101/404 reads (25%) | called by muse, mutect2, varscan2
- SLFN5 | c.-1G>C | 5'UTR (SNP) | VAF 68/134 reads (51%) | catalogued as COSV100249658; called by muse, mutect2, varscan2
